Somatic mutation profile of tumor specimen TCGA-B1-A47O-01A (aliquot TCGA-B1-A47O-01A-11D-A25F-10) from TCGA case TCGA-B1-A47O, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 54.3 years (19,823 days).
Specimen TCGA-B1-A47O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca46778d-008b-4646-b3e5-d69df8a91a0b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B1-A47O-10A (Blood Derived Normal), aliquot TCGA-B1-A47O-10A-01D-A25F-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8f950e05-c865-445c-bd97-d8d449f2ab52

The open-access MAF lists 40 somatic variants for this specimen: 24 protein-altering or splice-affecting, 11 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 11, Intron 2, 3'UTR 2, Frame Shift Ins 1, Splice Region 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASIP | c.223A>G p.K75E | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as rs538816237, COSV66588360; called by muse, mutect2, varscan2
- CETN1 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59121518; called by muse, mutect2, varscan2
- ERI3 | c.607C>T p.L203F | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64831990; called by muse, mutect2, varscan2
- F12 | c.866A>G p.Y289C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756656239, COSV53691671; called by mutect2, varscan2
- GALNT6 | c.959G>C p.R320P | Missense Mutation (SNP) | VAF 48/219 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs138580901, COSV62542466; called by muse, mutect2, varscan2
- HECTD4 | c.12383G>A p.G4128E | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66393536; called by muse, mutect2, varscan2
- IQCE | c.1763T>C p.V588A | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as COSV58079071; called by muse, mutect2, varscan2
- LPA | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.997); catalogued as rs779750198, COSV60303425; called by muse, varscan2
- LRP2 | c.12631G>A p.E4211K | Missense Mutation (SNP) | VAF 37/179 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55557490; called by muse, mutect2, varscan2
- NDUFB6 | c.183C>A p.V61= | Splice Region (SNP) | VAF 25/121 reads (21%) | catalogued as COSV63083518; called by muse, mutect2, varscan2
- NSUN3 | c.943G>T p.V315L | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58935944; called by muse, mutect2, varscan2
- PAF1 | c.748A>G p.M250V | Missense Mutation (SNP) | VAF 44/239 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.066); catalogued as COSV55394537; called by muse, mutect2, varscan2
- PIPOX | c.295G>C p.E99Q | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.485); catalogued as COSV60142286; called by muse, mutect2, varscan2
- POM121C | c.3274G>T p.G1092W (on ENST00000607367; = p.G850W on NM_001099415.3) | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57546488; called by muse, mutect2
- SCN2A | c.5704C>T p.R1902C | Missense Mutation (SNP) | VAF 37/190 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs367833365, CM034570; called by muse, mutect2, varscan2
- SECISBP2 | c.1777G>A p.V593I | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as COSV60528952; called by muse, mutect2, varscan2
- SPTBN4 | c.5531G>A p.R1844Q | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as rs556623605, COSV58951596; called by muse, mutect2, varscan2
- TMEM132C | c.1837G>A p.A613T | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV59424473; called by muse, mutect2, varscan2
- TRIP4 | c.1030G>C p.E344Q | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.828); catalogued as COSV56031320; called by muse, mutect2, varscan2
- TTN | c.47359T>A p.C15787S (on ENST00000591111; = p.C8363S on NM_003319.4) | Missense Mutation (SNP) | VAF 23/96 reads (24%) | PolyPhen probably damaging (0.996); catalogued as COSV60120528; called by muse, mutect2, varscan2
- FSCB | c.1808C>T p.A603V | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.101); called by muse, varscan2
- PFKP | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); called by mutect2, varscan2
- PTEN | c.629_634+5del p.X210_splice | Splice Site (DEL) | VAF 4/27 reads (15%) | called by mutect2, pindel
- SULT1C4 | c.826_827dup p.V277Pfs*16 | Frame Shift Ins (INS) | VAF 19/112 reads (17%) | called by mutect2, pindel, varscan2
- DNAH2 | c.12549C>G p.S4183= | Silent (SNP) | VAF 29/119 reads (24%) | catalogued as COSV66720737; called by muse, mutect2, varscan2
- EPHA8 | c.207G>A p.T69= | Silent (SNP) | VAF 43/210 reads (20%) | catalogued as rs781774323, COSV51272256; called by muse, mutect2, varscan2
- ERC1 | c.2499T>A p.R833= (on ENST00000360905 / NM_178040.4; = p.R805= on NM_178039.4) | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV61696028; called by muse, mutect2, varscan2
- ESPL1 | c.996A>T p.P332= | Silent (SNP) | VAF 67/271 reads (25%) | catalogued as COSV57760024; called by muse, mutect2, varscan2
- KCNN3 | c.2028G>A p.S676= (on ENST00000618040 / NM_001204087.1; = p.S661= on NM_002249.6) | Silent (SNP) | VAF 28/107 reads (26%) | catalogued as rs1217131264, COSV55214532; called by muse, mutect2, varscan2
- MAGEB2 | c.579C>G p.L193= | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as COSV66780939; called by muse, mutect2, varscan2
- MTUS2 | c.2565C>T p.V855= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV54988457, COSV99686570; called by muse, mutect2, varscan2
- PCDH15 | c.5553C>T p.N1851= | Silent (SNP) | VAF 5/128 reads (4%) | catalogued as COSV57327965; called by muse, mutect2
- PCLO | c.12987T>C p.S4329= | Silent (SNP) | VAF 52/188 reads (28%) | catalogued as COSV61640680; called by muse, mutect2, varscan2
- SNX3 | c.471T>G p.S157= | Silent (SNP) | VAF 19/103 reads (18%) | catalogued as COSV57778998; called by muse, mutect2, varscan2
- SRRM1 | c.1170T>C p.P390= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as rs199715936, COSV60478066; called by muse, mutect2, varscan2
- CD300LD | chr17:74592880 C>T | 5'Flank (SNP) | VAF 41/280 reads (15%) | called by muse, mutect2, varscan2
- ETNK2 | c.519-798G>A | Intron (SNP) | VAF 10/56 reads (18%) | called by muse, mutect2, varscan2
- MSRA | c.142+41336C>T | Intron (SNP) | VAF 16/118 reads (14%) | catalogued as COSV100412899; called by muse, mutect2, varscan2
- SLITRK5 | c.*489T>A | 3'UTR (SNP) | VAF 8/60 reads (13%) | catalogued as COSV100280680; called by muse, mutect2, varscan2
- TRO | c.*76T>C | 3'UTR (SNP) | VAF 28/248 reads (11%) | called by muse, mutect2, varscan2
